Surgical pathology report (de-identified scan), TCGA case TCGA-J2-A4AG, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J2-A4AG-01A (Primary Tumor).

[page 1 of 4]
Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Received

Time Reported

Order Number

Ordering Provider

Status

Final

Results

Final

Source of Specimen

- A. 4R-
- B. FS 4L LYMPH NODE-
- C. LEFT LOWER LOBE BRONCHIAL NODE-
- D. INTER LOBAR NODE-
- E. PULMONARY LIGAMENT-
- F. AP WINDOW NODE-
- G. NFS LEFT UPPER LOBE OF LUNG-
- H. FS LEFT UPPER LOBE LUNG-

ICD-0-3

adenocarcinoma, nos 8140/3

Site: lung, upper lobe C34.1

hw
9/24/12

FINAL DIAGNOSIS:

- A. 4R-
- LYMPH NODE, NO TUMOR SEEN (0/1).
- B. FS 4L LYMPH NODE-
- NO TUMOR SEEN IN MULTIPLE LYMPH NODE FRAGMENTS.
- C. LEFT LOWER LOBE BRONCHIAL NODE-
- NO TUMOR FOUND IN TWO LYMPH NODES (0/2).
- D. INTER LOBAR NODE-
- NO TUMOR SEEN IN TWO LYMPH NODES (0/2).
- E. PULMONARY LIGAMENT-
- NO TUMOR SEEN IN TWO LYMPH NODES (0/2).
- F. AP WINDOW NODE-
- LYMPH NODE, NO TUMOR SEEN (0/1).
- G. NFS LEFT UPPER LOBE OF LUNG-

INVASIVE CARCINOMA.

Prepared for

[page 2 of 4]
HISTOLOGIC TYPE: ADENOCARCINOMA.

HISTOLOGIC GRADE: 2/4.

TUMOR FOCALITY: UNIFOCAI.

TUMOR SIZE: 2.5 CM.

TUMOR SITE: LEFT UPPER LOBE.

TREATMENT EFFECT: NOT SEEN.

VISCERAL PLEURA INVASION: NOT PRESENT.

ATELECTASIS/OBSTRUCTIVE PNEUMONITIS EXTENDING TO HILUM: NOT SEEN.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

LARGE VESSEL INVASION: NOT SEEN.

0 OF 11 PERIBRONCHIAL NODES ARE POSITIVE FOR METASTATIC TUMOR.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 11

TNM STAGE: pT1b, pN0, pMX.

SPECIMEN TYPE: LOBECTOMY

SPECIMEN SIZE: 14 CM.

NO TUMOR SEEN AT RESECTION MARGINS.
H. FS LEFT UPPER LOBE LUNG-
SEE "G".

Signed Others

Frozen Section

A. 4L LYMPH NODE, FS: NO TUMOR SEEN.

LEFT UPPER LOBE OF LUNG, FS: LOBE OF LUNG WITH 2 SUTURE LINES.

ONE AREA ALREADY SECTIONED REVEALS A 2.5 CM FIRM MASS (1 SMALL
PORTION OF MASS REMOVED BY SURGEON). DX: ADENOCARCINOMA.

Prepared for

[page 3 of 4]
Case Clinical Information
LEFT UPPER LOBE NODULE

Gross Description

- A. Received in formalin labeled with the patient's name and "4R" is a dark brown fibroadipose tissue measuring 1 x 0.5 cm. Wrapped and entirely submitted in A1.
- B. Received in formalin labeled with the patient's name and "FS-4L lymph node" are five yellow/tan fibroadipose tissue fragments measuring 0.5 cm. Wrapped and entirely submitted in B1.
- C. Received in formalin labeled with the patient's name and "left lower lobe bronchial node" are two gray/brown fibroadipose tissue fragments. The larger fragment measures 1 x 1 cm; the smaller, 0.9 x 0.5 cm. Entirely submitted in C1.
- D. Received in formalin labeled with the patient's name and "interlobar lymph node" are two yellow/tan fibroadipose tissue fragments measuring 0.7 x 0.5 cm. Wrapped and entirely submitted in D1.
- E. Received in formalin labeled with the patient's name and "pulmonary ligament" are two yellow/tan fibroadipose tissue fragments. The larger fragment measuring 0.9 cm; the smaller, 0.4 cm. Wrapped and entirely submitted in E1.
- F. Received in formalin labeled with the patient's name and "AP window node" are three yellow/tan fibroadipose tissue fragments. The largest fragment measures 0.9 x 0.5 cm; the smallest, 0.7 x 0.5 cm. Entirely submitted in F1.
- G. Received in formalin labeled with the patient's name and "left upper lobe of lung-NFS" is a left upper lobe of lung weighing 150 grams and measuring 14 x 12 x 2 cm. The pleura is gray/brown with moderate anthracotic streaking and two staple lines which are removed and inked in red. The specimen has been previously sectioned from where frozen section has been taken showing a gray/tan, firm mass measuring 2.5 x 2.5 x 2.2 cm. The pleura and the lesion is inked in black. The remainder of the parenchyma is gray/brown, spongy. All the lesion is grossly identified. Three potential lymph nodes are grossly identified at the hilum. The largest measures 0.9 cm; the smallest, 0.5 cm. The specimen is represented as follows: bronchial resection margin in G1; tumor to the pleura in G2-G5; lung parenchyma to the red-inked staple resection margin in G6-G8; parenchyma away from the lesion in G9; one lymph node in G10;

Prepared for:

[page 4 of 4]
and two lymph nodes in G11.

H. Received in formalin labeled with the patient's name and "FS-left upper lobe of lung" is a gray/tan frozen section tissue fragment measuring 2.5 x 1.4 cm. Entirely submitted in H1.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK
H&E X1
- E. AA ROUTINE H&E X1 BLOCK
H&E X1
- F. AA ROUTINE H&E X1 BLOCK
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.7
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.8
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.9
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.10
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.11
H&E X1
- H. AA ROUTINE H&E X1 BLOCK
H&E X1

Prepared for

PAA Discrepancy		/
Qual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 2bc03ea2-7b79-495f-a948-2832606f674a (TCGA-J2-A4AG.E56191DA-873E-4506-8591-A6989706F8CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).